CPTAC case C3N-02682 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00bf9428-778d-456d-9c61-a0d46da7eef4

Demographics
Sex at birth: male; Race: white; Year of birth: 1959; Vital status: Dead; Days to death: 109 days; Year of death: 2017; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 58.4 years (21,329 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 109 days; Days to last follow up: 109 days.
   Pathology details: Greatest tumor dimension: 4 cm.

Follow-up (1 entry)
- Days to follow up: 109 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 76 kg; Height: 176 cm; BMI: 24.54.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02682-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -22 days; Initial weight: 264 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02682-22: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02682-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -21 days; Method of sample procurement: Blood Draw.
